Somatic mutation profile of tumor specimen TCGA-DE-A4MA-01A (aliquot TCGA-DE-A4MA-01A-11D-A257-08) from TCGA case TCGA-DE-A4MA, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 52.3 years (19,100 days).
Specimen TCGA-DE-A4MA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 298ff535-9088-4f81-b232-46a69a7d7d50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DE-A4MA-10A (Blood Derived Normal), aliquot TCGA-DE-A4MA-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e554a6ae-4a6c-4131-9ce3-74383cbae524

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CBLIF | c.672C>G p.Y224* | Nonsense Mutation (SNP) | VAF 11/111 reads (10%) | catalogued as COSV99951023; called by muse, mutect2, varscan2
- FSCN1 | c.128A>G p.K43R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1477575832, COSV100435236; called by muse, mutect2
- HIP1R | c.2074C>G p.L692V | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0.052); catalogued as COSV99459053; called by muse, mutect2, varscan2
- IGLV2-33 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 135/315 reads (43%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.014); catalogued as rs747035412; called by muse, mutect2, varscan2
- KIF21B | c.4567G>A p.D1523N (on ENST00000422435 / NM_001252100.2; = p.D1510N on NM_017596.4) | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV100144794; called by muse, mutect2, varscan2
- NLRP11 | c.273C>A p.R91= | Splice Region (SNP) | VAF 22/46 reads (48%) | catalogued as COSV100789781; called by muse, mutect2, varscan2
- OR4P4 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs747849915, COSV58920625, COSV58922652; called by muse, mutect2, varscan2
- PPP2R1A | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV59042465; called by muse, mutect2, varscan2
- CELSR2 | c.2754C>T p.P918= | Silent (SNP) | VAF 7/111 reads (6%) | catalogued as COSV99604339; called by muse, mutect2
